Somatic mutation profile of tumor specimen TCGA-BR-A44U-01A (aliquot TCGA-BR-A44U-01A-11D-A24D-08) from TCGA case TCGA-BR-A44U, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 70.0 years (25,577 days).
Specimen TCGA-BR-A44U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ace80ee-70d7-430a-9c32-edf13bb9cbe7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-A44U-10A (Blood Derived Normal), aliquot TCGA-BR-A44U-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32dcf6f3-fcb8-4fc3-b087-5c641d63f4f7

The open-access MAF lists 94 somatic variants for this specimen: 68 protein-altering or splice-affecting, 25 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 25, Frame Shift Del 4, Nonsense Mutation 4, 5'Flank 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RPL10L | c.467A>G p.K156R | Missense Mutation (SNP) | VAF 31/99 reads (31%) | hotspot (GDC flag); SIFT tolerated (0.12); PolyPhen probably damaging (0.97); catalogued as COSV53558657, COSV53559010, COSV53561078; called by muse, mutect2, varscan2
- TP53 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 22/44 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs786201059, CM076567, CM1212545, COSV52664318, COSV52687201, COSV52688214; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRA1 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as rs764981996, COSV66926550; called by muse, mutect2, varscan2
- ADGRB3 | c.3589C>T p.R1197* | Nonsense Mutation (SNP) | VAF 28/86 reads (33%) | catalogued as rs753963400, COSV53235554, COSV53239603; called by muse, mutect2, varscan2
- AL645922.1 | c.2117C>T p.T706M | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as rs558967629, COSV54961781; called by muse, mutect2, varscan2
- ARHGAP15 | c.293T>A p.L98Q | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.775); catalogued as rs764158566, COSV54510853; called by muse, mutect2, varscan2
- ARHGEF7 | c.68C>A p.T23N | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.021); catalogued as COSV57739202; called by muse, mutect2, varscan2
- BICDL2 | c.1009C>A p.P337T | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.056); catalogued as rs1351380582, COSV99560631; called by muse, mutect2, varscan2
- BICDL2 | c.547G>A p.G183R | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.68); catalogued as COSV54157300; called by muse, mutect2, varscan2
- CACNA1H | c.745G>A p.V249I | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs756266849, COSV61993629; called by muse, mutect2, varscan2
- CEACAM8 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.049); catalogued as rs994537637, COSV54991293; called by muse, mutect2, varscan2
- CFH | c.1933A>G p.T645A | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.037); catalogued as COSV66411239, COSV66412943; called by muse, mutect2, varscan2
- CHRNA9 | c.547G>A p.V183M | Missense Mutation (SNP) | VAF 56/168 reads (33%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.474); catalogued as rs1289001228, COSV59575354; called by muse, mutect2, varscan2
- CLEC1A | c.280G>C p.G94R | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.942); catalogued as COSV59533299; called by muse, mutect2, varscan2
- COL23A1 | c.1586C>T p.P529L | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.065); catalogued as COSV66787014; called by muse, mutect2, varscan2
- CPXM2 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774426425, COSV53867254; called by muse, mutect2, varscan2
- CSMD2 | c.5177C>T p.A1726V | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1418763276, COSV53896826; called by muse, mutect2, varscan2
- CSMD3 | c.2533C>T p.R845W (on ENST00000297405 / NM_001363185.1; = p.R741W on NM_052900.3) | Missense Mutation (SNP) | VAF 42/311 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747943730, COSV52258395; called by muse, mutect2, varscan2
- CST4 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.518); catalogued as rs150921984; called by muse, mutect2, varscan2
- CTAGE1 | c.2092G>T p.G698* | Nonsense Mutation (SNP) | VAF 64/132 reads (48%) | catalogued as COSV66944140; called by muse, mutect2, varscan2
- CTDNEP1 | c.711C>G p.N237K | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.754); catalogued as COSV56642539; called by muse, mutect2, varscan2
- DGKG | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.565); catalogued as rs764233443, COSV53961843; called by muse, mutect2, varscan2
- DGKI | c.382C>T p.R128W | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.841); catalogued as COSV55965384; called by muse, mutect2, varscan2
- EPB41L3 | c.2632G>A p.G878R | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.001); catalogued as rs140662824, COSV59453796; called by muse, mutect2, varscan2
- EXOC8 | c.1054_1055del p.D352Lfs*2 | Frame Shift Del (DEL) | VAF 24/110 reads (22%) | catalogued as rs752877756; called by pindel, varscan2
- FAM13A | c.1403G>A p.R468H | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.759); catalogued as rs116703634, COSV52008874; called by muse, mutect2, varscan2
- FLG2 | c.2821A>C p.S941R | Missense Mutation (SNP) | VAF 114/367 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.497); catalogued as rs776813566, COSV101165894, COSV66168956; called by muse, mutect2, varscan2
- GLI2 | c.4226C>T p.S1409L (on ENST00000361492 / NM_001374353.1; = p.S1426L on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.67); PolyPhen benign (0.3); catalogued as rs1215590067, COSV58035786; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GP2 | c.311C>T p.S104L | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as rs775810544, COSV56895587; called by muse, mutect2, varscan2
- GSK3A | c.1099-2A>G p.X367_splice | Splice Site (SNP) | VAF 7/22 reads (32%) | catalogued as COSV55900274; called by muse, mutect2
- HIPK2 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61230874; called by muse, mutect2, varscan2
- HTR1B | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 56/205 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.271); catalogued as COSV64051726; called by muse, mutect2
- INTS3 | c.625G>A p.V209I | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs1301742929, COSV59680182; called by muse, mutect2
- KLK13 | c.702G>A p.W234* | Nonsense Mutation (SNP) | VAF 29/110 reads (26%) | catalogued as COSV50067126, COSV50067388; called by muse, mutect2, varscan2
- LIN7A | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.03); catalogued as rs775944718, COSV54025105; called by mutect2, varscan2
- LONP1 | c.2752_2754del p.K918del | In Frame Del (DEL) | VAF 31/133 reads (23%) | catalogued as rs751060700; called by pindel, varscan2
- LRCH2 | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as rs1431509504, COSV57754567; called by muse, mutect2
- LRP1B | c.3523G>C p.E1175Q | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0.115); catalogued as rs1186175911, COSV67252735; called by muse, mutect2, varscan2
- MYH7B | c.5510C>T p.T1837M | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs372166400; called by muse, mutect2, varscan2
- NEUROD4 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV54470799, COSV54472887; called by muse, mutect2, varscan2
- NGB | c.418G>A p.V140I | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.112); catalogued as rs765144506, COSV53611503; called by muse, mutect2, varscan2
- PCDH15 | c.3314T>G p.L1105R | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as COSV57359275; called by muse, mutect2, varscan2
- PCSK7 | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs75310602, COSV56117931; called by muse, mutect2, varscan2
- PHLDB1 | c.2245G>A p.E749K | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as rs782609223, COSV61879474; called by muse, mutect2, varscan2
- POM121 | c.2131A>G p.T711A (on ENST00000434423; = p.T446A on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.05); catalogued as COSV57520834; called by muse, mutect2, varscan2
- PSME4 | c.3141C>A p.D1047E | Missense Mutation (SNP) | VAF 55/195 reads (28%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as COSV66366578; called by muse, mutect2, varscan2
- RAI14 | c.2663C>T p.S888L | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as rs928096502, COSV54292789; called by muse, mutect2, varscan2
- RALYL | c.157G>A p.V53I | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs749865840, COSV72819608; called by muse, mutect2, varscan2
- RIMS1 | c.623A>C p.K208T | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53471566, COSV99330109; called by muse, mutect2
- RP1L1 | c.2107C>T p.R703* | Nonsense Mutation (SNP) | VAF 20/37 reads (54%) | catalogued as rs775708703, COSV66751274; called by muse, mutect2, varscan2
- RPH3A | c.1717C>T p.R573C (on ENST00000389385 / NM_001143854.2; = p.R569C on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763849876, COSV66992196; called by muse, mutect2, varscan2
- SLC12A3 | c.793G>A p.V265M | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.603); catalogued as rs776260447, COSV52637326; called by muse, mutect2, varscan2
- SLC16A3 | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV66429492, COSV66429913; called by muse, mutect2
- SNTG1 | c.703G>T p.A235S | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.956); catalogued as rs752367805, COSV52458427; called by muse, mutect2, varscan2
- ST3GAL6 | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.061); catalogued as rs140152670; called by muse, mutect2, varscan2
- SYN1 | c.932A>G p.K311R | Missense Mutation (SNP) | VAF 30/43 reads (70%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as COSV55983613; called by muse, mutect2, varscan2
- TMPRSS9 | c.2369C>G p.P790R (on ENST00000648592; = p.P756R on NM_182973.2) | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV53114945; called by muse, mutect2, varscan2
- TRIML1 | c.512C>T p.T171I | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.987); catalogued as COSV60195815; called by muse, mutect2, varscan2
- TTN | c.12462G>A p.M4154I (on ENST00000591111; = p.M4108I on NM_003319.4) | Missense Mutation (SNP) | VAF 57/195 reads (29%) | catalogued as rs1283675443, COSV60173032; called by muse, mutect2, varscan2
- UBOX5 | c.326T>A p.V109D | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.074); catalogued as COSV53907936; called by muse, mutect2, varscan2
- UNC45A | c.1168A>G p.N390D | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as COSV67817167; called by muse, mutect2, varscan2
- UVSSA | c.1244A>C p.E415A | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV66230483; called by muse, mutect2, varscan2
- ZNF484 | c.1517C>G p.T506S | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0.191); catalogued as rs1303041703, COSV60258932; called by muse, mutect2, varscan2
- ZNF516 | c.2377C>G p.P793A | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.079); catalogued as COSV71587411; called by muse, mutect2, varscan2
- ZNF521 | c.3058T>G p.F1020V | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV64129848; called by muse, mutect2, varscan2
- NF1 | c.640_641del p.N214* | Frame Shift Del (DEL) | VAF 16/39 reads (41%) | called by mutect2, pindel, varscan2
- SACS | c.11311_11326del p.K3771Yfs*22 | Frame Shift Del (DEL) | VAF 20/109 reads (18%) | called by mutect2, pindel, varscan2
- WDR17 | c.3282_3318del p.N1094Kfs*35 | Frame Shift Del (DEL) | VAF 20/60 reads (33%) | called by mutect2, pindel
- ADCY8 | c.792C>T p.Y264= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as rs1386540850, COSV53897730; called by muse, mutect2
- CHIA | c.1107C>T p.G369= (on ENST00000343320; = p.G261= on NM_021797.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV58477067; called by muse, mutect2, varscan2
- CSMD3 | c.1983A>G p.K661= (on ENST00000297405 / NM_001363185.1; = p.K557= on NM_052900.3) | Silent (SNP) | VAF 48/391 reads (12%) | catalogued as COSV52139570; called by muse, mutect2, varscan2
- DNAJC5B | c.294C>T p.N98= | Silent (SNP) | VAF 40/268 reads (15%) | catalogued as COSV52536941; called by muse, mutect2, varscan2
- FAM47C | c.1824G>A p.P608= | Silent (SNP) | VAF 36/62 reads (58%) | catalogued as rs781902699, COSV63727941; called by muse, mutect2, varscan2
- FRMD3 | c.42C>T p.T14= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as COSV58466045; called by muse, mutect2, varscan2
- GPER1 | c.381C>T p.A127= | Silent (SNP) | VAF 43/125 reads (34%) | catalogued as rs780063298, COSV52468425; called by muse, mutect2, varscan2
- HELLS | c.1341C>T p.F447= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV53299790; called by muse, mutect2, varscan2
- IGSF11 | c.552C>A p.T184= (on ENST00000393775 / NM_001015887.3; = p.T183= on NM_152538.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as COSV61174525; called by muse, mutect2, varscan2
- ISYNA1 | c.876G>A p.A292= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV54211557; called by muse, mutect2, varscan2
- ITIH5 | c.1407G>A p.S469= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as rs373527198, COSV99904292; called by muse, mutect2, varscan2
- KCNC2 | c.1233C>T p.N411= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as rs200648638, COSV100128147, COSV54373983; called by muse, mutect2, varscan2
- KCNT2 | c.1392C>A p.T464= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV54096309, COSV99657457; called by muse, mutect2, varscan2
- MAP1S | c.468G>A p.T156= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as rs747118489, COSV60722740; called by muse, mutect2, varscan2
- NOTUM | c.1338C>T p.N446= | Silent (SNP) | VAF 10/99 reads (10%) | catalogued as rs763866532, COSV68826398; called by muse, mutect2
- PAPPA | c.2883C>T p.D961= | Silent (SNP) | VAF 108/204 reads (53%) | catalogued as rs751713023, COSV60288679; called by muse, mutect2, varscan2
- PAPPA2 | c.1206T>G p.S402= | Silent (SNP) | VAF 37/102 reads (36%) | catalogued as COSV62782776; called by muse, mutect2, varscan2
- PGAP4 | c.549G>A p.S183= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as rs535197432, COSV66388136; called by muse, mutect2, varscan2
- PTPN13 | c.6525C>T p.N2175= (on ENST00000411767 / NM_080683.3; = p.N2156= on NM_006264.3) | Silent (SNP) | VAF 30/117 reads (26%) | catalogued as rs765749481, COSV57412975; called by muse, mutect2, varscan2
- RIOK3 | c.993A>G p.K331= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV59774243; called by muse, mutect2, varscan2
- SCN7A | c.2817T>C p.F939= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV69268345, COSV69273501; called by muse, mutect2, varscan2
- SPEG | c.1080G>A p.S360= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV56675801; called by muse, mutect2, varscan2
- SPPL2C | c.1818C>T p.D606= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as rs374530875; called by muse, mutect2, varscan2
- SUN3 | c.480G>A p.P160= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as rs150352113; called by muse, mutect2, varscan2
- TUBA3C | c.309C>T p.Y103= | Silent (SNP) | VAF 34/137 reads (25%) | catalogued as rs114178008, COSV67139668; called by muse, mutect2, varscan2
- VPS11 | chr11:119067998 C>T | 5'Flank (SNP) | VAF 9/23 reads (39%) | catalogued as COSV56186413; called by muse, mutect2, varscan2
